Somatic mutation profile of tumor specimen TCGA-AB-2936-03A (aliquot TCGA-AB-2936-03A-01W-0745-08) from TCGA case TCGA-AB-2936, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,280 days).
Specimen TCGA-AB-2936-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3d092f6-9304-4daf-9531-ceacbe28ed14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2936-11A (Solid Tissue Normal), aliquot TCGA-AB-2936-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b317d6d7-4649-4ddc-8a58-121f15a3c354

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C7orf26 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); catalogued as COSV100253891; called by muse, mutect2
- GABBR1 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs753230530, COSV63543603; called by muse, mutect2
- TMEM251 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF319 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTL9 | c.501C>T p.F167= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs1555753419, COSV61004888; called by muse, varscan2
- COL5A3 | c.3033G>A p.E1011= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs765165742, COSV53406903; called by muse, mutect2, varscan2
- ERF | c.1488G>T p.G496= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99724608; called by muse, mutect2, varscan2
- HAS3 | c.870C>T p.Y290= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1382460386, COSV99544258; called by muse, mutect2, varscan2
- WDR64 | c.1698G>C p.L566= | Silent (SNP) | VAF 114/262 reads (44%) | catalogued as COSV63793050; called by muse, mutect2, varscan2
